Gene-level copy-number profile of tumor specimen TCGA-13-1498-01A from TCGA case TCGA-13-1498, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.4 years (26,820 days).
Specimen TCGA-13-1498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.12975196-6e03-4f58-ab1d-ddbf2f9e9d15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1498-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96a59d80-17b9-4678-abc5-6dc1bdb7dc1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 18,070; copy number 2: 31,876; copy number 3: 7,818; copy number 4: 1,722; copy number 5: 199; copy number 6: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1498-01A-01D-0472-01): tumor purity 0.89, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:208,255,290–208,270,667, 2 genes: AL606753.1, AL606753.2.
- chr3:186,842,704–192,119,864, 64 genes (broad region; genes not listed).
- chr16:65,601,101–65,601,698, 1 gene: AC092138.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 258 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,841,093–159,897,366, 10 genes, copy number 5 (within-gene range 4–5): GPR79, AC092999.1, IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P.
- chr3:160,399,274–180,037,053, 248 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,651. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
